Surgical pathology report (de-identified scan), TCGA case TCGA-VD-AA8P, project TCGA-UVM (Uveal Melanoma), tissue source site University of Liverpool, specimen TCGA-VD-AA8P-01A (Primary Tumor).

[page 1 of 3]
Department of Pathology			HISTOPATHOLOGY		
Surname	Lab No		Clinical Consultant & Location		
Forename(s)	DOB/Age	Sex			
Unit No	Request Date				

This Copy For:

SPECIMEN

RIGHT GLOBE ENUCLEATION, PROGNOSTIC AND DIAGNOSTIC

CLINICAL DETAILS

See diagram. Measurements 10.63 x 10.18 x (10.37)mm

MACROSCOPIC DESCRIPTION

A fresh, intact, right globe.

Dimensions: Axial 25mm, Horizontal 23.5mm, Vertical 24mm

Cornea: Horizontal 12.5mm, Vertical 12mm

Optic nerve: flesh

On trans-illumination, a shadow is seen in the inferolateral position, approx 13mm.

Plane of section: vertical

Intraocular description:

A solitary dome shaped, pigmented choroidal mass is seen. Prominent vessels arising from optic disc. IOL is present.

Tumour size

LBD 12mm, Height 10.5mm

MICROSCOPY

Sections show a pigmented choroidal melanoma consisting predominantly of spindle cells. Tumour cells express Melan-A and HSP 27 (score 3).

The number of mitosis is approximately 8/40 high power fields. The microvasculature of the melanoma is prominent, and closed loops are present in the planes of sections. The lymphocytic infiltrate within the tumour is minimal. Tumour necrosis is not seen. There is no tumour extension through the sclera, optic nerve or vortex veins examined. Tumour cells are not seen at the resection margins.

ICD-O-3
Melanoma, spindle cell, type B 8774/3
Site: (B) Choroid C69.3
JN 5/30/14

Reported:

Pathologist:

Electronically Verified:

[page 2 of 3]
Department of Pathology

Page 2 of 3

HISTOPATHOLOGY REPORT Tel:

Surname [REDACTED]	Lab No [REDACTED]		Clinical Consultant & Location [REDACTED] [REDACTED]
Forename(s) [REDACTED]	DOB/Age [REDACTED]	Sex [REDACTED]	
Unit No [REDACTED] [REDACTED]	Request Date [REDACTED]		

This Copy For: [REDACTED]

Elsewhere, the cornea shows no significant abnormality. The anterior chamber angles are open and the anterior chamber is deep. The iris shows no significant abnormality but the ciliary body appears atrophic with hyalinisation of ciliary processes. Residual peripheral cataractuous lens is identified. Retina overlying the tumour is slightly atrophic.

DIAGNOSIS

Right eye, enucleation: Choroidal melanoma of predominantly spindle cell type.

SUMMARY

SPECIMEN	2= Eye
TUMOUR PRESENT	Yes
TUMOUR TYPE	1= Melanoma
CELL TYPE	2= Spindle B
CT LOOPS	2= Closed loops
NECROSIS	No
PIGMENTATION	Yes
LYMPHOCYTIC INFILTRATION	No
MITOTIC FREQUENCY	8/40 HPF
DIFFUSE MELANOMA	No
SPREAD	1= No
CLEARANCE	2= Adequate
HSP-27 POSITIVITY	3= >70%
LARGE DIAMETER	12 mm
THICKNESS	10.5 mm

COMMENT

Molecular genetic examination of DNA extracted from the tumour cells will be performed using multiplex-ligation

Reported:

Pathologist: [REDACTED]

Electronically Verified: [REDACTED]

[page 3 of 3]
Department of Pathology

Page 3 of 3

HISTOPATHOLOGY REPORT Tel:

Surname [REDACTED]	Lab No [REDACTED]	Clinical Consultant & Location [REDACTED]	
Forename(s) [REDACTED]	DOB/Age [REDACTED]	Sex [REDACTED]	[REDACTED]
Unit No [REDACTED]	Request Date [REDACTED]		

This Copy For: [REDACTED]

dependent probe amplification (MLPA), looking at chromosomes 1, 3, 6 and 8. A supplementary report will follow in due course.

SUPPLEMENTARY REPORT - MLPA

In the meantime, molecular genetic analysis of tumour DNA extracted from the fresh uveal melanoma tissue was performed using the technique termed multiplex ligation-dependent probe amplification (MLPA). These investigations were performed in the

The kit P027 from [REDACTED], which examines for gains or losses in 31 loci on chromosomes 1, 3, 6 and 8, was used. The DNA concentration was measured using [REDACTED] and the quality assessed using multiplex-PCR prior to the MLPA reaction.

The DNA concentration was high and of good quality on assessment. The MLPA reaction was run at least twice on differing occasions, resulting in similar results.

The results of the sequence analysis of the MLPA products is printed on a separate report. In summary, sequence analysis demonstrated:

loss of chromosome 1p,
monosomy 3,
normal chromosome 6
and gains in chromosome 8.

Taken together, these molecular data would place the patient in the high risk group with respect to the development of metastatic melanoma.

Consideration of clinical features of the tumour is, however, also required.

Reported:

Pathologist: [REDACTED]

Electronically Verified: [REDACTED]

Primary Tumour Site Discrepancy		✓

Source: NCI Genomic Data Commons file 5a8387b8-c532-4581-a7fb-cbeac66e7027 (TCGA-VD-AA8P.EAADA209-BED3-4FA3-B39C-2428BF278EF7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).